Somatic mutation profile of tumor specimen MP2PRT-PAPBLE-TMP1-A (aliquot MP2PRT-PAPBLE-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAPBLE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,392 days).
Specimen MP2PRT-PAPBLE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a193da3f-a087-4bc7-a72f-5839b2da705b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPBLE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPBLE-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b4b433c-05eb-4dba-8017-62bdc6b5c104

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Intron 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA3 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 252/585 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs769185929, COSV55626188; called by muse, mutect2, varscan2
- ESYT3 | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 148/432 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200786117; called by muse, mutect2, varscan2
- FLT3 | c.1768_1769insCAGAAGATT p.Y589_F590insSED | In Frame Ins (INS) | VAF 63/279 reads (23%) | catalogued as COSV54064180; called by mutect2, pindel, varscan2
- HAO1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 157/486 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780268660, COSV101113224; called by muse, mutect2, varscan2
- NBN | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs1554566728; ClinVar: uncertain significance; called by muse, mutect2
- OCA2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 185/448 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs151118268; called by muse, mutect2, varscan2
- PCDHA12 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 359/872 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.604); catalogued as rs200398819; called by muse, mutect2, varscan2
- RASA3 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 46/479 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs377496833; called by muse, mutect2
- CDC45 | c.723T>G p.D241E | Missense Mutation (SNP) | VAF 140/500 reads (28%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.583); called by mutect2, varscan2
- CDK19 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HDX | c.1356G>T p.K452N | Missense Mutation (SNP) | VAF 212/706 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MARCO | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 158/451 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- SPNS2 | c.991G>C p.A331P | Missense Mutation (SNP) | VAF 315/700 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TENM2 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 145/470 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- URB1 | c.6491G>A p.G2164E | Missense Mutation (SNP) | VAF 274/1218 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BACE1 | c.1125G>A p.T375= | Silent (SNP) | VAF 164/460 reads (36%) | catalogued as rs75519595; called by muse, mutect2, varscan2
- CABIN1 | c.2646G>A p.T882= | Silent (SNP) | VAF 32/535 reads (6%) | catalogued as rs755875223; called by muse, mutect2
- FAAH2 | c.579A>T p.S193= | Silent (SNP) | VAF 197/662 reads (30%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.327C>T p.S109= | Silent (SNP) | VAF 31/697 reads (4%) | catalogued as rs199931341, COSV57792993; called by muse, mutect2
- KCNQ1 | c.1514+6194A>T | Intron (SNP) | VAF 210/472 reads (44%) | called by muse, mutect2, varscan2
- NPAP1L | n.221C>T | RNA (SNP) | VAF 123/310 reads (40%) | catalogued as rs2897598, COSV73747278; called by muse, mutect2, varscan2
